CPTAC case C3L-07637 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1c368cd-17d0-4c42-b6da-ce7e048c3b92

Demographics
Sex at birth: male; Race: white; Year of birth: 1956; Vital status: Alive; Country of birth: Romania.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Pylorus; Age at diagnosis: 64.9 years (23,702 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 1,230 days (3.4 years); Progression or recurrence: no; Days to last follow up: 1,230 days (3.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph nodes tested: 49.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 167 days; Days to treatment end: 231 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 860 days (2.4 years); Disease response: Stable Disease; Karnofsky performance status: 100; ECOG performance status: 0.
- Follow-up contact recording only the day: day 526.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2009; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07637-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 91 days; Initial weight: 181 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07637-21: Section location: Pylorus; Percent tumor nuclei: 70; Percent necrosis: 3.
- Sample C3L-07637-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 91 days; Initial weight: 90 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07637-22: Section location: Pylorus; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-07637-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 91 days; Method of sample procurement: Blood Draw.
